Somatic mutation profile of tumor specimen TCGA-DK-A1AC-01A (aliquot TCGA-DK-A1AC-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.0 years (26,307 days).
Specimen TCGA-DK-A1AC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03c46be1-5552-45d2-9cb7-eb0846f6906e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AC-10A (Blood Derived Normal), aliquot TCGA-DK-A1AC-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7982c369-1ced-4aab-b7b1-be41f5a846af

The open-access MAF lists 1,725 somatic variants for this specimen: 1,187 protein-altering or splice-affecting, 482 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,022, Silent 482, Nonsense Mutation 101, Intron 22, Splice Site 20, Frame Shift Del 15, Splice Region 13, RNA 12, 5'UTR 9, 5'Flank 7, Frame Shift Ins 6, In Frame Del 6.

Variants (750 of 1,725; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540131; called by muse, mutect2, varscan2
- FBXW7 | c.1637C>T p.S546L (on ENST00000281708 / NM_001349798.2; = p.S466L on NM_018315.5) | Missense Mutation (SNP) | VAF 92/122 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55905633, COSV99656643, COSV99660447; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RUNX1 | c.319G>C p.A107P (on ENST00000344691 / NM_001001890.3; = p.A134P on NM_001754.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315451, CM021675, COSV55873549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 61/112 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV55289112; called by muse, mutect2, varscan2
- AAGAB | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56016493; called by muse, mutect2, varscan2
- ABCA1 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 76/114 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs551884479, CM1210656, COSV66064183; called by muse, mutect2, varscan2
- ABCA12 | c.6992C>T p.S2331L (on ENST00000272895 / NM_173076.3; = p.S2013L on NM_015657.3) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV55955292; called by muse, mutect2, varscan2
- ABCA12 | c.3971C>T p.S1324F (on ENST00000272895 / NM_173076.3; = p.S1006F on NM_015657.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV55955310, COSV99791062; called by muse, mutect2, varscan2
- ABCC2 | c.3314G>A p.C1105Y | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV64985587; called by muse, mutect2, varscan2
- ABCD2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV58051164; called by muse, mutect2, varscan2
- ABHD16A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.006); catalogued as COSV65442747; called by muse, mutect2, varscan2
- ABI3BP | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV52533644; called by muse, mutect2, varscan2
- AC004832.3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV56741657; called by muse, mutect2
- AC104452.1 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55534026; called by mutect2, varscan2
- AC126283.2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 113/137 reads (82%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs143366614, CM1311019; ClinVar: benign; called by muse, mutect2, varscan2
- ACAN | c.6655G>A p.E2219K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61358969; called by muse, mutect2, varscan2
- ACBD5 | c.238G>A p.E80K (on ENST00000375888 / NM_001352568.1; = p.E82K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV65518725; called by muse, mutect2, varscan2
- ACER1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1465298560, COSV56835230; called by muse, mutect2, varscan2
- ACLY | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61250264; called by muse, mutect2, varscan2
- ACP3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV60485450; called by muse, mutect2, varscan2
- ACP5 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535958; called by muse, mutect2, varscan2
- ACSL5 | c.1739C>T p.S580L (on ENST00000354273; = p.S636L on NM_016234.3) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV61130068, COSV61132545; called by muse, mutect2, varscan2
- ACSS1 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs781232536, COSV60221505; called by muse, mutect2, varscan2
- ACSS3 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 101/122 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV54085632, COSV54097587; called by muse, mutect2, varscan2
- ADAM10 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV53050919; called by muse, mutect2, varscan2
- ADAM33 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs146682885, COSV62934385; called by muse, mutect2, varscan2
- ADAMTS8 | c.1770G>C p.Q590H | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV57292707; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 88/112 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV54998650; called by muse, mutect2, varscan2
- ADCK5 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216558051, COSV58233241; called by muse, mutect2, varscan2
- ADGRE5 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs757930051, COSV54409791; called by muse, varscan2
- ADGRG2 | c.821C>G p.P274R (on ENST00000379869 / NM_001079858.3; = p.P271R on NM_005756.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV61338524; called by muse, mutect2, varscan2
- ADGRL2 | c.1654G>C p.G552R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV54662865; called by muse, mutect2, varscan2
- ADGRL3 | c.2660C>T p.S887L (on ENST00000506720 / NM_001322402.2; = p.S819L on NM_015236.6) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72230216; called by muse, mutect2, varscan2
- ADK | c.136G>A p.D46N (on ENST00000286621; = p.D29N on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs375984437; called by muse, mutect2, varscan2
- ADRA1D | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs759003942, COSV65240572, COSV65241755; called by muse, mutect2, varscan2
- AFAP1L2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV58413897; called by muse, mutect2, varscan2
- AFM | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.82); catalogued as COSV56919752; called by muse, mutect2, varscan2
- AGBL2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as rs745670607, COSV54091269; called by muse, mutect2, varscan2
- AGL | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV54051374; called by muse, mutect2, varscan2
- AHNAK2 | c.13121G>A p.G4374E | Missense Mutation (SNP) | VAF 102/179 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV60912856; called by muse, mutect2, varscan2
- AKAP13 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV63453801; called by muse, mutect2, varscan2
- AKAP13 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63453814, COSV63464038; called by muse, mutect2, varscan2
- AKAP9 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV62343434; called by muse, mutect2, varscan2
- AKAP9 | c.5788G>A p.E1930K (on ENST00000359028; = p.E1898K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV62343449; called by muse, mutect2, varscan2
- AKR1B1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV53647035; called by muse, mutect2, varscan2
- AL021546.1 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as COSV57569278; called by muse, mutect2, varscan2
- AL592490.1 | c.2497C>T p.L833F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69425627; called by muse, mutect2, varscan2
- AMOTL2 | c.2265delinsAA p.R756Kfs*98 (on ENST00000422605; = p.R757Kfs*98 on NM_016201.4) | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | catalogued as COSV51438606; called by mutect2*, pindel, varscan2*
- ANAPC1 | c.4589C>T p.S1530L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1446951650, COSV61975464; called by muse, mutect2, varscan2
- ANK2 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs751513548, COSV52156051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4507C>T p.P1503S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51844873; called by muse, mutect2, varscan2
- ANKRD30A | c.3761C>T p.S1254F (on ENST00000611781; = p.S1198F on NM_052997.2) | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs549672970, COSV100654194, COSV64608283; called by muse, mutect2, varscan2
- ANKRD52 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as COSV57283759; called by muse, mutect2, varscan2
- ANO2 | c.873C>G p.N291K (on ENST00000356134 / NM_001278597.3; = p.N295K on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59017438; called by muse, mutect2, varscan2
- ANO3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV56787883; called by muse, mutect2, varscan2
- ANO6 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57659739; called by muse, varscan2
- ANO7 | c.349G>T p.E117* (on ENST00000274979; = p.E62* on NM_001001666.4) | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as rs1559439895; called by muse, mutect2, varscan2
- ANO7 | c.2572G>A p.E858K (on ENST00000274979; = p.E804K on NM_001370694.2) | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51470586; called by muse, mutect2, varscan2
- ANP32E | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 334/497 reads (67%) | catalogued as COSV58482806; called by muse, mutect2, varscan2
- AP1G2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV58111887; called by muse, mutect2, varscan2
- AP4B1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 90/169 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56724377; called by muse, mutect2, varscan2
- APC | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57334984, COSV57338113; called by muse, mutect2, varscan2
- APC2 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV52017586; called by muse, mutect2, varscan2
- APEH | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56533121; called by muse, mutect2, varscan2
- APP | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs760615902, COSV60997213; called by muse, mutect2, varscan2
- APP | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60997221; called by muse, mutect2
- AQR | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV50032023; called by muse, mutect2, varscan2
- ARFRP1 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60831763; called by muse, mutect2, varscan2
- ARHGAP32 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59843113; called by muse, mutect2, varscan2
- ARHGEF18 | c.2197G>A p.E733K (on ENST00000359920 / NM_001130955.2; = p.E629K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV60468902; called by muse, varscan2
- ARL14 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57899720; called by muse, mutect2, varscan2
- ARL4A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV63319203; called by muse, mutect2, varscan2
- ARNT2 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV57583786; called by muse, mutect2, varscan2
- ASCC2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57073062; called by muse, mutect2, varscan2
- ASH2L | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51699239; called by muse, mutect2, varscan2
- ASXL2 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710580; called by muse, mutect2
- ATG5 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100576517, COSV58347343; called by muse, mutect2, varscan2
- ATIC | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52692622; called by muse, mutect2, varscan2
- ATP10D | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV56706419; called by muse, mutect2, varscan2
- ATP10D | c.3532C>G p.L1178V | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV56706427; called by muse, mutect2, varscan2
- ATP11A | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs770429974, COSV52109832; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as COSV67777819; called by muse, mutect2, varscan2
- ATP6V1H | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62217828; called by muse, mutect2, varscan2
- ATP8B1 | c.858T>G p.F286L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV52174608; called by muse, mutect2, varscan2
- ATP8B1 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781375943, COSV52174883; called by muse, mutect2, varscan2
- ATP8B3 | c.3207G>C p.Q1069H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59541899; called by muse, mutect2, varscan2
- ATRIP | c.2356C>G p.P786A (on ENST00000320211 / NM_130384.3; = p.P759A on NM_032166.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56496758; called by muse, mutect2
- AVIL | c.2347-5_2359del p.X783_splice | Splice Site (DEL) | VAF 18/72 reads (25%) | catalogued as COSV57681231; called by mutect2, pindel, varscan2
- AXDND1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62641571; called by muse, mutect2, varscan2
- B3GNT2 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV57344379; called by muse, mutect2, varscan2
- B4GALNT3 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56751647; called by muse, mutect2, varscan2
- BAG3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as COSV64841898; called by muse, mutect2
- BCHE | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs751406038, COSV52255641; called by muse, mutect2, varscan2
- BCL9L | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571501612, COSV52683526; called by muse, mutect2, varscan2
- BCLAF1 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV62141531; called by muse, mutect2, varscan2
- BEST4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as COSV64733811; called by muse, mutect2, varscan2
- BFSP1 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV64902070; called by muse, mutect2, varscan2
- BHLHE40 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56575330; called by muse, mutect2, varscan2
- BHLHE41 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV54378511; called by muse, mutect2, varscan2
- BIRC6 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as COSV70197967; called by muse, mutect2, varscan2
- BIRC6 | c.12614C>T p.S4205L | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV70194960; called by muse, mutect2, varscan2
- BLMH | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV55585026; called by muse, mutect2, varscan2
- BLMH | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV55585037; called by muse, mutect2, varscan2
- BLNK | c.900G>A p.Q300= | Splice Region (SNP) | VAF 50/124 reads (40%) | catalogued as COSV56410203; called by muse, mutect2, varscan2
- BMP5 | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63702491; called by muse, varscan2
- BMPR1B | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52776335; called by muse, mutect2, varscan2
- BMS1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.136); catalogued as rs1485096253, COSV65733602; called by muse, mutect2, varscan2
- BNIP5 | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs1219797403, COSV71325485; called by muse, mutect2, varscan2
- BTG2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV51855779; called by muse, mutect2
- BUB1B | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55011322; called by muse, mutect2, varscan2
- BUD23 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56094744; called by muse, mutect2, varscan2
- C1QTNF12 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV57802505; called by muse, mutect2, varscan2
- C1orf141 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV63992473; called by muse, mutect2, varscan2
- C2CD3 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58092110; called by muse, mutect2, varscan2
- C2orf49 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51527436; called by muse, mutect2, varscan2
- C3orf62 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55536203; called by muse, mutect2, varscan2
- C4BPA | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100891093, COSV65536185; called by muse, mutect2, varscan2
- C5orf15 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV51548269; called by muse, mutect2, varscan2
- C6orf136 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV53313414; called by muse, mutect2, varscan2
- C9orf43 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55912428; called by muse, mutect2, varscan2
- CACNA1A | c.5833G>C p.D1945H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1193365931, COSV64195362; called by muse, mutect2, varscan2
- CACNA1F | c.2119-1G>A p.X707_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV59903674, COSV59903990; called by muse, mutect2, varscan2
- CACNA1I | c.5683G>A p.E1895K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100360303, COSV60805661; called by muse, mutect2, varscan2
- CAD | c.5596G>A p.E1866K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.899); catalogued as COSV53025619; called by muse, mutect2, varscan2
- CALHM4 | c.820G>A p.D274N (on ENST00000368596 / NM_001366078.1; = p.D88N on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV63985534; called by muse, mutect2, varscan2
- CAPSL | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV68437826; called by muse, mutect2, varscan2
- CARD11 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as COSV62754881; called by muse, varscan2
- CARD6 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 92/421 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs760860157, COSV54564427, COSV99621417; called by muse, mutect2, varscan2
- CARMIL3 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as rs1326286773, COSV57725868; called by muse, mutect2, varscan2
- CARMIL3 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV57725873; called by muse, mutect2, varscan2
- CASQ1 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV63624042; called by muse, mutect2, varscan2
- CATSPERB | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV56425000; called by muse, mutect2, varscan2
- CBX8 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs760284596, COSV53936150; called by muse, varscan2
- CCDC142 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as COSV51777148; called by muse, mutect2, varscan2
- CCDC151 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV52950987, COSV52951320; called by muse, mutect2, varscan2
- CCDC28B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV52208488; called by mutect2, varscan2
- CCDC38 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV60182793; called by muse, mutect2, varscan2
- CCDC40 | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53898577; called by muse, mutect2, varscan2
- CCDC51 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56488688; called by muse, mutect2, varscan2
- CCDC60 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV59542601; called by muse, mutect2, varscan2
- CCDC63 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as rs753076766, COSV57528087; called by muse, mutect2, varscan2
- CCDC88C | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66237097; called by muse, varscan2
- CCL21 | c.117G>C p.K39N | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.856); catalogued as COSV52398746; called by muse, mutect2, varscan2
- CCL3L3 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1264839370; called by muse, mutect2, varscan2
- CCNB3 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52072292; called by muse, mutect2, varscan2
- CCNC | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV58333957; called by muse, mutect2, varscan2
- CCNH | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs1448141189, COSV56924642; called by muse, mutect2, varscan2
- CCNH | c.491A>C p.Y164S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56924651; called by muse, mutect2, varscan2
- CCT8L2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs892552559, COSV63462141; called by muse, mutect2, varscan2
- CD109 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV54648137; called by muse, mutect2, varscan2
- CD164 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV51533293; called by muse, mutect2, varscan2
- CDH16 | c.1599G>C p.Q533H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs1356957059, COSV55336097; called by muse, mutect2, varscan2
- CDH4 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV64649894; called by muse, mutect2, varscan2
- CDHR5 | c.2453A>T p.E818V (on ENST00000358353 / NM_001171968.2; = p.E824V on NM_021924.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV57642326; called by muse, mutect2, varscan2
- CDHR5 | c.2452G>A p.E818K (on ENST00000358353 / NM_001171968.2; = p.E824K on NM_021924.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs1393278064, COSV57642332, COSV57642954; called by muse, mutect2, varscan2
- CDK14 | c.646G>A p.D216N (on ENST00000380050 / NM_001287135.2; = p.D198N on NM_012395.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV56031238; called by muse, mutect2, varscan2
- CDK16 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV52091699; called by muse, mutect2
- CDK16 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); catalogued as COSV52091725; called by muse, mutect2
- CDK16 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV52091753; called by muse, mutect2, varscan2
- CDK3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764108595, COSV56909699; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1793C>G p.S598C (on ENST00000357886 / NM_001365728.1; = p.S584C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV55786654; called by muse, mutect2, varscan2
- CDKAL1 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV51181545, COSV51182106; called by muse, mutect2
- CDKN1A | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.754); catalogued as COSV55188159; called by muse, mutect2, varscan2
- CDKN1B | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 74/108 reads (69%) | catalogued as COSV57429744, COSV57429936; called by muse, mutect2, varscan2
- CDKN2D | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765714251, COSV57264248; called by muse, mutect2, varscan2
- CEBPA | c.881T>A p.I294N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57196959; called by muse, mutect2, varscan2
- CENPT | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV54649051; called by muse, mutect2, varscan2
- CEP162 | c.3334C>T p.Q1112* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as COSV57620626; called by muse, mutect2, varscan2
- CEP250 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV61169355, COSV61172641; called by muse, mutect2, varscan2
- CERCAM | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.13); catalogued as COSV65710773; called by muse, mutect2, varscan2
- CETP | c.1249-1G>A p.X417_splice | Splice Site (SNP) | VAF 41/71 reads (58%) | catalogued as COSV52362176; called by muse, mutect2, varscan2
- CFAP45 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745611980, COSV63648696; called by muse, mutect2, varscan2
- CFAP46 | c.7735C>T p.Q2579* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99585824; called by muse, mutect2, varscan2
- CFAP54 | c.5294C>T p.S1765F | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV61571702; called by muse, mutect2, varscan2
- CHD3 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57874106; called by muse, mutect2, varscan2
- CHD8 | c.5788G>A p.D1930N (on ENST00000646647 / NM_001170629.2; = p.D1651N on NM_020920.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63036720; called by muse, mutect2, varscan2
- CHRNA9 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560318004, COSV59574201; called by muse, mutect2, varscan2
- CHST14 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs751335857, COSV60378625; called by muse, mutect2, varscan2
- CHUK | c.1850_1852del p.K617del | In Frame Del (DEL) | VAF 33/75 reads (44%) | catalogued as rs1438845560; called by pindel, varscan2
- CHUK | c.1729+1G>A p.X577_splice | Splice Site (SNP) | VAF 25/127 reads (20%) | catalogued as COSV64917642; called by muse, mutect2, varscan2
- CITED2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62726374; called by muse, mutect2, varscan2
- CLCA4 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1251631486, COSV55367589; called by muse, mutect2, varscan2
- CLEC3B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56109600; called by muse, mutect2, varscan2
- CLPP | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1283241021, COSV55536425; called by muse, mutect2, varscan2
- CMTR1 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65090081; called by muse, mutect2, varscan2
- CNDP2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs775655898, COSV60839550; called by muse, mutect2, varscan2
- CNKSR1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs974069843, COSV64163123; called by muse, mutect2, varscan2
- CNOT3 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV55364075; called by muse, mutect2, varscan2
- CNOT4 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59651412; called by muse, mutect2, varscan2
- COG4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs387907202, CM110993, COSV60422122; called by muse, mutect2, varscan2
- COL19A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59570355; called by muse, mutect2, varscan2
- COL22A1 | c.3551A>G p.D1184G | Missense Mutation (SNP) | VAF 71/453 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as COSV57332346; called by muse, mutect2, varscan2
- COL27A1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV61924758; called by muse, mutect2, varscan2
- COL7A1 | c.8683C>T p.R2895W | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs751882294, COSV56476352; called by muse, mutect2, varscan2
- COP1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.682); catalogued as COSV58165668; called by muse, varscan2
- COPA | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 386/506 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54100588; called by muse, varscan2
- COPS4 | c.624_631del p.N209Lfs*10 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as COSV52314471; called by mutect2, pindel, varscan2
- CPA6 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52726477; called by muse, mutect2, varscan2
- CPLX2 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853010, COSV64000199; called by muse, varscan2
- CPNE2 | c.1634C>G p.S545W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV51961933; called by muse, mutect2, varscan2
- CPQ | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV55142981; called by muse, mutect2, varscan2
- CPT1A | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV55754962; called by muse, mutect2, varscan2
- CREB3L3 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV50184825; called by muse, mutect2, varscan2
- CRELD1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV55976881; called by muse, mutect2, varscan2
- CRISP3 | c.580C>G p.L194V (on ENST00000371159 / NM_001368123.1; = p.L176V on NM_006061.4) | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV53819951; called by muse, mutect2, varscan2
- CRMP1 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1456611479, COSV61478544; called by muse, mutect2, varscan2
- CROCC | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65011406; called by muse, mutect2, varscan2
- CRTC3 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as rs1411951091, COSV51595834; called by muse, mutect2, varscan2
- CRY2 | c.747G>C p.W249C | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV69888382; called by muse, mutect2, varscan2
- CSE1L | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); catalogued as rs372551577; called by muse, mutect2, varscan2
- CSGALNACT2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.259); catalogued as COSV65675384; called by muse, mutect2, varscan2
- CSRP3 | c.509T>A p.V170D | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.216); catalogued as COSV56389341; called by muse, mutect2, varscan2
- CST1 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV59055022; called by muse, mutect2, varscan2
- CST9L | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs1257125818, COSV65407775; called by muse, mutect2, varscan2
- CUL5 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV67608636; called by muse, mutect2, varscan2
- CUL9 | c.5371G>C p.E1791Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV52727556; called by muse, mutect2, varscan2
- CUTC | c.620G>T p.R207I | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65081702; called by muse, mutect2, varscan2
- CX3CL1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245922123, COSV50055684; called by muse, mutect2, varscan2
- CX3CR1 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV64193163; called by muse, mutect2, varscan2
- CYLC2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.327); catalogued as rs1445690327, COSV66337146; called by muse, mutect2, varscan2
- CYP3A7 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 119/234 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV60481172; called by muse, mutect2, varscan2
- CYP46A1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55894060; called by muse, mutect2, varscan2
- CYP7B1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV59586283; called by muse, mutect2, varscan2
- CYTH4 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV50631887; called by muse, mutect2, varscan2
- DAAM2 | c.2596C>G p.L866V | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as COSV51309009; called by muse, mutect2, varscan2
- DBH | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV55040400; called by muse, mutect2, varscan2
- DCAF10 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 104/156 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV54287820; called by muse, mutect2, varscan2
- DCAF12 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63511669; called by muse, mutect2, varscan2
- DCAF4L2 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60477835; called by muse, mutect2, varscan2
- DCLK1 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55181462; called by muse, mutect2, varscan2
- DCLRE1A | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63748513, COSV63749736; called by muse, mutect2, varscan2
- DCPS | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1333538222, COSV55010512; called by muse, mutect2, varscan2
- DCTN2 | c.761G>A p.G254E (on ENST00000548249 / NM_001261413.2; = p.G259E on NM_006400.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as rs753967632, COSV63073963; called by muse, mutect2, varscan2
- DDB1 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57101598, COSV57102216; called by muse, mutect2, varscan2
- DDI2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | catalogued as rs1416854324, COSV100197657; called by muse, mutect2, varscan2
- DDIAS | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs142883872; called by muse, mutect2, varscan2
- DDX11 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52505893; called by muse, mutect2, varscan2
- DDX55 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV53015792; called by muse, mutect2, varscan2
- DEFB123 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV66233390; called by muse, mutect2, varscan2
- DENND1C | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV57568374; called by muse, mutect2, varscan2
- DHCR24 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV64874513; called by muse, varscan2
- DHX29 | c.2194C>A p.L732I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52417697; called by muse, mutect2, varscan2
- DHX32 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1194164076, COSV52939524; called by muse, mutect2, varscan2
- DHX9 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV62358998; called by muse, mutect2, varscan2
- DIP2B | c.4168C>G p.L1390V | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56582007, COSV99999130; called by muse, mutect2, varscan2
- DIPK2B | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV65005418; called by muse, mutect2
- DKK1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV64760149; called by muse, mutect2, varscan2
- DKK2 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV53396284; called by muse, mutect2, varscan2
- DLGAP1 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.638); catalogued as COSV59797388; called by muse, mutect2, varscan2
- DLGAP5 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV55962850; called by muse, mutect2, varscan2
- DMXL1 | c.7588C>T p.L2530F | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60709109, COSV60717649; called by muse, varscan2
- DMXL1 | c.7663C>T p.H2555Y | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767036060, COSV60709127; called by muse, varscan2
- DNAAF3 | c.1588C>T p.P530S (on ENST00000524407 / NM_001256715.2; = p.P577S on NM_178837.4) | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.215); catalogued as COSV61276437; called by muse, mutect2, varscan2
- DNAH3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs751103410, COSV51785211, COSV51785396; called by muse, mutect2, varscan2
- DNAI4 | c.1834A>T p.I612L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV64021409; called by muse, mutect2, varscan2
- DNAJA1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV58310138; called by muse, mutect2, varscan2
- DNAJC13 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV53448969; called by muse, mutect2, varscan2
- DNAJC16 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV65448374; called by muse, mutect2, varscan2
- DNAJC28 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV58721508; called by muse, mutect2, varscan2
- DOCK7 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51996220, COSV52002182, COSV52011081; called by muse, mutect2, varscan2
- DOT1L | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67109105; called by muse, mutect2, varscan2
- DPYSL4 | c.1170A>C p.K390N | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58306812; called by muse, mutect2, varscan2
- DST | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203501748, COSV56810446; called by muse, varscan2
- DST | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100424973; called by muse, mutect2, varscan2
- DTNA | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV51999014; called by muse, mutect2, varscan2
- DTNB | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV56475257; called by muse, mutect2, varscan2
- DTX1 | c.1164G>C p.K388N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV57496785; called by muse, mutect2, varscan2
- DTX1 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55655217; called by muse, mutect2, varscan2
- DUS1L | c.698-1G>C p.X233_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV57648581; called by muse, mutect2, varscan2
- DUSP10 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 100/163 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60457357; called by muse, mutect2, varscan2
- DVL2 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200445258, COSV50038910; called by muse, mutect2, varscan2
- DXO | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61713268; called by muse, mutect2, varscan2
- DYNC1H1 | c.12865G>A p.D4289N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.337); catalogued as rs368476290; called by muse, mutect2, varscan2
- ECPAS | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52195469; called by muse, mutect2, varscan2
- EDC3 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59339839; called by muse, mutect2, varscan2
- EDN2 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1039710418, COSV65423424; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV61080047; called by muse, mutect2, varscan2
- EFR3A | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54455704; called by muse, mutect2, varscan2
- EGFLAM | c.3029A>C p.N1010T (on ENST00000354891 / NM_001205301.2; = p.N1002T on NM_152403.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59298525; called by muse, mutect2, varscan2
- EIF3F | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV59141905; called by muse, mutect2, varscan2
- EIF4G3 | c.3770T>C p.V1257A | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV51675275, COSV51679726; called by muse, mutect2, varscan2
- EIF5B | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV56812352; called by muse, mutect2, varscan2
- ELMOD3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV55707093; called by muse, varscan2
- ELP2 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV60850397; called by muse, mutect2, varscan2
- ELP2 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV60850413; called by muse, mutect2, varscan2
- EMC1 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV64345575; called by muse, mutect2, varscan2
- EMILIN3 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs758137757, COSV60035305; called by muse, mutect2, varscan2
- EN1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1388739739, COSV54631473; called by muse, mutect2, varscan2
- ENC1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV56629287; called by muse, mutect2, varscan2
- ENTPD3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as rs1271910931, COSV57194044; called by muse, mutect2, varscan2
- EPB42 | c.1933G>A p.E645K (on ENST00000441366 / NM_001114134.2; = p.E675K on NM_000119.3) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs941557171, COSV55746847; called by muse, mutect2, varscan2
- EPHB6 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV63891305; called by muse, mutect2, varscan2
- EPM2AIP1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV51616771; called by muse, mutect2, varscan2
- EPRS1 | c.4192G>C p.E1398Q | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.74); catalogued as COSV65098345; called by muse, varscan2
- EPYC | c.166-1G>C p.X56_splice | Splice Site (SNP) | VAF 52/147 reads (35%) | catalogued as rs10859087, COSV53799330; called by mutect2, varscan2
- ERC2 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV55614559; called by muse, mutect2, varscan2
- ETV1 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54140522, COSV54147776; called by muse, mutect2, varscan2
- EVC2 | c.3599G>C p.R1200P | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60391554; called by muse, mutect2
- EVC2 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV60391586; called by muse, mutect2, varscan2
- EVI5 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63278638; called by muse, mutect2, varscan2
- EXOSC2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1364784713, COSV64910530; called by muse, mutect2, varscan2
- EZR | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as COSV61455942; called by muse, mutect2, varscan2
- FAM102B | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV64239670; called by muse, mutect2, varscan2
- FAM162B | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV63920248; called by muse, mutect2, varscan2
- FAM169A | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV65846346; called by muse, mutect2, varscan2
- FAM172A | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs761854218, COSV67936616; called by muse, mutect2, varscan2
- FAM228A | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV54595200; called by muse, mutect2, varscan2
- FAM83C | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV65582707; called by muse, varscan2
- FAM83D | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368793717, COSV54157231; called by muse, varscan2
- FANCD2 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55036087; called by muse, mutect2
- FANCD2 | c.3333C>T p.L1111= | Splice Region (SNP) | VAF 181/211 reads (86%) | catalogued as rs956067003, COSV55036103; called by muse, mutect2, varscan2
- FANCF | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59416008; called by muse, mutect2, varscan2
- FCGBP | c.8851G>A p.E2951K | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs758034809; called by muse, varscan2
- FCGR2B | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV52681210; called by muse, varscan2
- FCN3 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54641021; called by muse, mutect2, varscan2
- FCRL4 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 225/315 reads (71%) | SIFT tolerated (0.82); PolyPhen benign (0.019); catalogued as COSV54861537; called by muse, mutect2, varscan2
- FEM1C | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57231308, COSV99174372; called by muse, mutect2, varscan2
- FETUB | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 108/217 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV54005333; called by muse, mutect2, varscan2
- FGD1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as COSV64308535; called by muse, mutect2, varscan2
- FGD5 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53240723, COSV53250279, COSV99549019; called by muse, mutect2, varscan2
- FGF13 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as rs1433430358, COSV65433225; called by muse, mutect2, varscan2
- FGFR2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60644568; called by muse, mutect2, varscan2
- FGFR2 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.285); catalogued as rs1396687223, COSV60644575, COSV60653406; called by muse, mutect2, varscan2
- FGL1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67712236; called by muse, mutect2, varscan2
- FGR | c.1515C>G p.F505L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64969431; called by muse, mutect2, varscan2
- FGR | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.05); catalogued as COSV64969433; called by muse, varscan2
- FIBCD1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs371088741; called by muse, mutect2, varscan2
- FLNB | c.3405A>T p.K1135N | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55876371; called by muse, mutect2, varscan2
- FNDC3B | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.477); catalogued as COSV61040443; called by muse, mutect2
- FOXD4L1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV52073805; called by muse, mutect2, varscan2
- FOXH1 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100023853, COSV56760704; called by muse, mutect2, varscan2
- FOXJ3 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62361731; called by muse, mutect2, varscan2
- FOXJ3 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV62361738; called by muse, mutect2, varscan2
- FRMD8 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1270578962, COSV58212285; called by muse, mutect2, varscan2
- FRYL | c.7366G>A p.D2456N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV51944678; called by muse, mutect2, varscan2
- FSTL4 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54768085; called by muse, mutect2, varscan2
- FSTL4 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551036078, COSV54766493; called by muse, mutect2, varscan2
- FTL | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV53169810; called by muse, mutect2, varscan2
- GABARAP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56641784, COSV56643163; called by muse, mutect2, varscan2
- GABRG1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV54950691, COSV54952481; called by muse, mutect2, varscan2
- GABRR1 | c.1344G>C p.M448I | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV101033789, COSV65619177; called by muse, mutect2, varscan2
- GALNT11 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV57425395; called by muse, mutect2, varscan2
- GANAB | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV60463764; called by muse, mutect2
- GANAB | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV60463790; called by muse, mutect2, varscan2
- GAS2 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53406557; called by muse, mutect2, varscan2
- GCC1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50000760, COSV50001716; called by muse, mutect2
- GFPT1 | c.1129C>G p.H377D (on ENST00000357308 / NM_001244710.2; = p.H359D on NM_002056.4) | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV61947530; called by muse, varscan2
- GGA2 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 291/342 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59168150; called by muse, mutect2, varscan2
- GIPC3 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV59258769; called by muse, mutect2, varscan2
- GLB1L2 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60278259; called by muse, mutect2, varscan2
- GLI1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs766134206, COSV57360639; called by muse, mutect2, varscan2
- GLRX3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58692182; called by muse, mutect2, varscan2
- GLS | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV57841073; called by muse, mutect2, varscan2
- GNA14 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV59022138; called by muse, varscan2
- GNAI3 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63983565; called by muse, mutect2, varscan2
- GNB1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV66100148; called by muse, varscan2
- GNB1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV66100153; called by muse, varscan2
- GNB5 | c.1099G>A p.E367K (on ENST00000261837 / NM_016194.4; = p.E325K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV55898850; called by muse, mutect2, varscan2
- GON4L | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 52/425 reads (12%) | catalogued as COSV55191640; called by muse, mutect2, varscan2
- GPC6 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs761341422, COSV65530559; called by muse, mutect2
- GPCPD1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); catalogued as COSV66830550; called by muse, mutect2, varscan2
- GPR158 | c.1907C>G p.S636* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as COSV100894450; called by muse, mutect2, varscan2
- GPR83 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54718214, COSV54720143; called by muse, varscan2
- GPR89B | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1342505755, COSV58501534; called by muse, mutect2, varscan2
- GPRC6A | c.1080T>G p.H360Q | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.342); catalogued as COSV59952533; called by muse, mutect2, varscan2
- GRAP2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59994714; called by muse, mutect2, varscan2
- GRIA3 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52055793; called by muse, mutect2, varscan2
- GRIA3 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332595145, COSV52051448, COSV52056557; called by muse, mutect2, varscan2
- GRIK1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266308913, COSV58715516; called by muse, mutect2, varscan2
- GRIK5 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53477316; called by mutect2, varscan2
- GRK6 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62682326; called by muse, mutect2, varscan2
- GRPEL2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs746181511, COSV61387528; called by muse, mutect2, varscan2
- GSTM2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV53982240; called by muse, mutect2, varscan2
- GUCY1A2 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56483878; called by muse, mutect2, varscan2
- H1-5 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58899709; called by muse, mutect2, varscan2
- H2AW | c.133_151del p.G45Ifs*9 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as COSV64209681; called by mutect2, pindel, varscan2
- H2BC5 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as COSV56800630, COSV56801968; called by muse, mutect2, varscan2
- H2BC5 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.506); catalogued as rs772836222, COSV56799773, COSV56799958, COSV56800667; called by muse, mutect2, varscan2
- H2BC6 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV61590978; called by muse, mutect2, varscan2
- H3C13 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.27); catalogued as rs1553755006, COSV58944125; called by muse, mutect2, varscan2
- H3C3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV63550652, COSV63551431, COSV63551470; called by muse, mutect2, varscan2
- HACD1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336564953, COSV63516251; called by muse, mutect2, varscan2
- HAL | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 110/282 reads (39%) | catalogued as COSV54117316; called by muse, mutect2, varscan2
- HAS2 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV58263291; called by muse, mutect2, varscan2
- HCCS | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV58239004; called by muse, mutect2, varscan2
- HCFC1 | c.2113C>G p.P705A | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.426); catalogued as COSV60071376; called by muse, mutect2, varscan2
- HCRTR1 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV65483612; called by muse, mutect2, varscan2
- HEATR1 | c.3205G>C p.E1069Q | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV63980669; called by muse, mutect2, varscan2
- HECTD1 | c.3618G>C p.E1206D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as COSV67945865; called by muse, mutect2, varscan2
- HECW1 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV67826886; called by muse, mutect2, varscan2
- HEPHL1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV100244620; called by muse, mutect2, varscan2
- HEPHL1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.173); catalogued as COSV59891127; called by muse, mutect2, varscan2
- HERC1 | c.4483G>C p.E1495Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.954); catalogued as COSV71247174; called by muse, varscan2
- HERC1 | c.3388C>T p.Q1130* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV71247866; called by muse, mutect2, varscan2
- HERC4 | c.1713del p.K572Nfs*23 | Frame Shift Del (DEL) | VAF 50/230 reads (22%) | catalogued as COSV53269995; called by pindel, varscan2
- HES1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51684402, COSV51684593, COSV99220395; called by muse, mutect2, varscan2
- HHIP | c.105G>T p.R35S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56838628; called by muse, mutect2, varscan2
- HIGD2A | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 54/130 reads (42%) | catalogued as COSV51257379; called by muse, mutect2, varscan2
- HIKESHI | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs868726094, COSV53573957; called by muse, mutect2, varscan2
- HK3 | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV52839896; called by muse, mutect2, varscan2
- HLX | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65044654; called by muse, mutect2, varscan2
- HMCN1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV54892425; called by muse, mutect2, varscan2
- HNRNPK | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV61089201; called by muse, mutect2, varscan2
- HOOK2 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs373017050; called by muse, mutect2, varscan2
- HPCAL1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57145445; called by muse, mutect2, varscan2
- HRAS | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV54240049, COSV54245466; called by muse, mutect2, varscan2
- HS6ST1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267598868, COSV52127752; called by muse, mutect2, varscan2
- HSF4 | c.1288G>C p.E430Q (on ENST00000521374 / NM_001040667.3; = p.E400Q on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50456957; called by muse, mutect2, varscan2
- HSPG2 | c.8207C>T p.S2736L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV65970693, COSV65970830; called by muse, varscan2
- HTR7 | c.386C>G p.S129W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53285346; called by muse, mutect2, varscan2
- HYDIN | c.13996G>A p.E4666K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs1409406266; called by muse, mutect2, varscan2
- ICE1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99666085; called by muse, mutect2, varscan2
- IER2 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV52847783; called by muse, mutect2, varscan2
- IFNL3 | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV69829896; called by muse, mutect2, varscan2
- IGDCC3 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60077232; called by muse, mutect2, varscan2
- IGHG4 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs773942746; called by muse, mutect2, varscan2
- IGLV4-60 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101135274; called by muse, mutect2, varscan2
- IGSF21 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52130544; called by muse, mutect2, varscan2
- IGSF8 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV58757802; called by muse, mutect2, varscan2
- IKBKB | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV60596953; called by muse, mutect2, varscan2
- IL17RC | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs112532783; called by muse, mutect2, varscan2
- IL3RA | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV58430308, COSV58430759; called by muse, mutect2, varscan2
- IL9R | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.655); catalogued as COSV54899020; called by muse, mutect2, varscan2
- IMPDH2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1310959844, COSV58244664; called by muse, mutect2, varscan2
- IMPG1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64056696; called by muse, mutect2, varscan2
- INHBE | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1433473305, COSV56987870; called by muse, mutect2, varscan2
- INPP5A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61248333; called by muse, mutect2, varscan2
- INSR | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV57158448, COSV57174151; called by muse, mutect2, varscan2
- INTS14 | c.606-1G>A p.X202_splice (on ENST00000313182 / NM_001366360.2; = p.X123_splice on NM_001136043.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV57526655; called by muse, mutect2, varscan2
- INTS7 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV65344098; called by muse, mutect2, varscan2
- IPO4 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55779388; called by muse, mutect2, varscan2
- IPP | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV63432409; called by muse, mutect2, varscan2
- IQSEC1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as rs747210938, COSV56221241; called by muse, mutect2, varscan2
- IRS1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59335364; called by muse, mutect2, varscan2
- ISLR | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51433466; called by muse, mutect2, varscan2
- ITCH | c.2251G>A p.E751K (on ENST00000262650 / NM_001257137.3; = p.E710K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV52931114; called by muse, mutect2, varscan2
- ITGB1BP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs755295860, COSV53005837; called by muse, mutect2, varscan2
- ITPR2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as rs1385731545, COSV54383801, COSV99659612; called by muse, mutect2, varscan2
- IVNS1ABP | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as COSV62249960; called by muse, mutect2, varscan2
- JAG1 | c.2343G>A p.Q781= | Splice Region (SNP) | VAF 54/155 reads (35%) | catalogued as COSV54755774; called by muse, varscan2
- JAM3 | c.411G>A p.V137= | Splice Region (SNP) | VAF 21/72 reads (29%) | catalogued as COSV54452016; called by muse, mutect2, varscan2
- JMJD1C | c.3688C>A p.P1230T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59514103; called by muse, mutect2, varscan2
- JMJD1C | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV67860489; called by muse, mutect2, varscan2
- JOSD2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs749166920, COSV67119090; called by mutect2, varscan2
- KCNC4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63925284, COSV99056742; called by muse, mutect2, varscan2
- KCNJ1 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV60661674; called by muse, mutect2, varscan2
- KCNQ4 | c.531C>T p.I177= | Splice Region (SNP) | VAF 37/84 reads (44%) | catalogued as COSV61272680; called by muse, mutect2, varscan2
- KCNQ5 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs763590853, COSV59654339; called by muse, mutect2, varscan2
- KCNQ5 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as rs373955161; called by muse, mutect2, varscan2
- KCNT2 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV54074211; called by muse, mutect2, varscan2
- KCTD19 | c.2629G>C p.D877H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58572255; called by muse, mutect2, varscan2
- KCTD4 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.676); catalogued as COSV61239020; called by muse, mutect2, varscan2
- KDM4C | c.3059G>C p.R1020T | Missense Mutation (SNP) | VAF 145/205 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV67185673; called by muse, mutect2, varscan2
- KDM7A | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV50090840; called by muse, mutect2, varscan2
- KERA | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV57130373; called by muse, varscan2
- KHDRBS3 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 145/234 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV63416846; called by muse, mutect2, varscan2
- KIAA0100 | c.1583G>C p.R528P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.879); catalogued as COSV66491990; called by muse, mutect2, varscan2
- KIAA0319L | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV57844397; called by muse, mutect2, varscan2
- KIAA1217 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298738789, COSV56815327; called by muse, mutect2, varscan2
- KIF16B | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61704734; called by muse, mutect2
- KIF22 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV50714580; called by muse, mutect2, varscan2
- KIF23 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV52978919; called by muse, mutect2, varscan2
- KIR2DL3 | c.539C>A p.T180K | Missense Mutation (SNP) | VAF 56/815 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1243375752; called by muse, mutect2
- KIT | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.328); catalogued as rs1490714621, COSV55389841, COSV55394370; called by muse, mutect2, varscan2
- KLF11 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59940237; called by muse, mutect2, varscan2
- KLHDC2 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.067); catalogued as COSV53587024; called by muse, mutect2, varscan2
- KLHL10 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53172957; called by muse, mutect2, varscan2
- KLHL18 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51745012; called by muse, mutect2, varscan2
- KMT2A | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV63284552, COSV63286241; called by muse, mutect2, varscan2
- KMT2D | c.6775G>A p.E2259K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.169); catalogued as COSV56428770, COSV99983068; called by muse, varscan2
- KMT2E | c.4099C>G p.Q1367E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57571945; called by muse, mutect2, varscan2
- KMT5A | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.91); catalogued as COSV57862801; called by muse, mutect2, varscan2
- KRCC1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.874); catalogued as rs746015002, COSV61251363; called by muse, mutect2, varscan2
- KRT25 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56444472, COSV56446589; called by muse, mutect2, varscan2
- KRT3 | c.1336A>G p.I446V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.826); catalogued as rs1391820866, COSV58815227; called by muse, mutect2, varscan2
- KRT39 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62917075; called by muse, mutect2, varscan2
- KRT40 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV66696258; called by muse, mutect2, varscan2
- KRTAP1-5 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs549554201, COSV100721356, COSV62624171; called by muse, varscan2
- LAMA2 | c.7449A>C p.A2483= | Splice Region (SNP) | VAF 10/47 reads (21%) | catalogued as COSV70344463; called by muse, varscan2
- LAMA3 | c.5850G>C p.Q1950H (on ENST00000313654 / NM_198129.4; = p.Q341H on NM_000227.6) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV52533197, COSV52535741; called by muse, mutect2, varscan2
- LAMA5 | c.2467T>C p.Y823H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756235294, COSV53357815; called by muse, mutect2, varscan2
- LAMP3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 63/141 reads (45%) | catalogued as COSV55614067; called by muse, mutect2, varscan2
- LCA5 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.055); catalogued as COSV63971134; called by muse, mutect2, varscan2
- LCP1 | c.1763C>G p.S588C | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59940415, COSV59940477, COSV59943533; called by muse, mutect2, varscan2
- LDB3 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53940016; called by muse, mutect2, varscan2
- LEAP2 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV51527717; called by muse, mutect2, varscan2
- LEMD3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV57649694; called by muse, mutect2, varscan2
- LEO1 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55175419; called by muse, mutect2, varscan2
- LGALS13 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55679790; called by muse, mutect2, varscan2
- LGI2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 124/208 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66122753; called by muse, varscan2
- LHPP | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100919178; called by muse, mutect2, varscan2
- LHPP | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV64328885; called by muse, mutect2
- LILRA5 | c.87C>T p.L29= | Splice Region (SNP) | VAF 10/96 reads (10%) | catalogued as rs201892026, COSV56642271; called by muse, mutect2
- LINS1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.187); catalogued as COSV59078618; called by muse, mutect2, varscan2
- LIPE | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV54922260, COSV54923319; called by muse, mutect2, varscan2
- LIPI | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs751166636, COSV100753530, COSV60710297; called by muse, mutect2, varscan2
- LPA | c.4582T>C p.S1528P | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); catalogued as COSV60300370; called by muse, mutect2, varscan2
- LPIN1 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs374190632; called by muse, mutect2, varscan2
- LRCH4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs779466665, COSV53825203; called by muse, mutect2, varscan2
- LRFN5 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV53251679; called by muse, mutect2, varscan2
- LRP12 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV52627692; called by muse, mutect2, varscan2
- LRP1B | c.6976G>A p.D2326N | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67206151; called by muse, mutect2, varscan2
- LRP2 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV55552511; called by muse, mutect2, varscan2
- LRP4 | c.4747G>A p.D1583N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV66135264; called by muse, mutect2, varscan2
- LRRC1 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63823510; called by muse, mutect2, varscan2
- LRRC73 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52500412; called by muse, mutect2, varscan2
- LRRC8E | c.396_405del p.T133Gfs*52 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | catalogued as COSV60717675; called by mutect2, pindel, varscan2
- LRRK2 | c.6805G>A p.D2269N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.048); catalogued as rs1311301966, COSV54149866; called by muse, mutect2, varscan2
- LTBP4 | c.2051G>A p.R684Q (on ENST00000308370 / NM_001042544.1; = p.R647Q on NM_003573.2) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as rs765063019, COSV52584181; called by muse, mutect2
- LUZP2 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61201423; called by muse, mutect2, varscan2
- MACF1 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV58368772; called by muse, mutect2, varscan2
- MACF1 | c.20449G>C p.E6817Q (on ENST00000372915; = p.E4862Q on NM_012090.5) | Missense Mutation (SNP) | VAF 95/189 reads (50%) | catalogued as COSV57116964; called by muse, mutect2, varscan2
- MACF1 | c.21847G>A p.D7283N (on ENST00000372915; = p.D5328N on NM_012090.5) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | catalogued as rs1163784106, COSV57116983, COSV57146428; called by muse, mutect2, varscan2
- MAGI2 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62632451, COSV62646618, COSV62699477; called by muse, mutect2, varscan2
- MAMDC4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV56032516; called by muse, mutect2, varscan2
- MAN1A1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV63782144; called by muse, mutect2, varscan2
- MAN1A2 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV62977630; called by muse, mutect2, varscan2
- MAOA | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV58642400, COSV58643545; called by muse, mutect2, varscan2
- MAP3K5 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV62888648; called by muse, mutect2, varscan2
- MAP3K7 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV65224132; called by muse, varscan2
- MAPKAPK2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54315537; called by muse, mutect2, varscan2
- MARCHF9 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV56984548; called by muse, mutect2, varscan2
- MARK2 | c.989-1G>A p.X330_splice | Splice Site (SNP) | VAF 51/114 reads (45%) | catalogued as COSV59282341; called by muse, mutect2, varscan2
- MATR3 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV63078762; called by muse, mutect2, varscan2
- MATR3 | c.2532G>C p.K844N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV63076848; called by muse, mutect2, varscan2
- MCC | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56727372; called by muse, mutect2, varscan2
- MCC | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV56727382; called by muse, mutect2, varscan2
- MCM8 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV52543321, COSV99177509; called by muse, mutect2, varscan2
- MEA1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV55144664; called by muse, mutect2, varscan2
- MED1 | c.1160G>C p.S387T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV56123948; called by muse, mutect2, varscan2
- MED12 | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV61336917; called by muse, mutect2, varscan2
- MED13 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV67262973; called by muse, mutect2, varscan2
- MED13L | c.5176-1G>C p.X1726_splice | Splice Site (SNP) | VAF 20/69 reads (29%) | catalogued as COSV56118482; called by muse, mutect2, varscan2
- MEFV | c.2180G>C p.G727A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54820704; called by muse, mutect2, varscan2
- MEIOC | c.2072G>A p.R691K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV63439774; called by muse, mutect2, varscan2
- METTL3 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52968360; called by muse, mutect2, varscan2
- MFN1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54939141; called by muse, mutect2, varscan2
- MMP12 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58259119, COSV58260360; called by muse, mutect2, varscan2
- MMS22L | c.2669G>C p.R890P | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV51519763, COSV51523249; called by muse, mutect2, varscan2
- MPDZ | c.3814G>A p.D1272N | Missense Mutation (SNP) | VAF 89/145 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs1361591231, COSV59916797; called by muse, mutect2, varscan2
- MROH2B | c.4666C>T p.R1556C | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs933563945, COSV68181661; called by muse, mutect2, varscan2
- MRPL15 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1055460808, COSV52637327; called by muse, mutect2, varscan2
- MRPL17 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV56618283; called by muse, mutect2, varscan2
- MRPL43 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs752700572, COSV52967445; called by muse, mutect2, varscan2
- MRPL45 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs549274705; called by muse, varscan2
- MRPL58 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV56900596; called by muse, mutect2, varscan2
- MRPS18B | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV52541296; called by muse, mutect2
- MS4A14 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV55729510; called by muse, mutect2, varscan2
- MS4A2 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV54012248, COSV54013880; called by mutect2, varscan2
- MSI2 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV52356637; called by muse, mutect2, varscan2
- MST1 | c.492T>A p.N164K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.967); catalogued as COSV56533126; called by muse, mutect2, varscan2
- MTHFD1 | c.2049C>G p.I683M | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53699525; called by muse, mutect2, varscan2
- MTIF2 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55051052; called by muse, mutect2, varscan2
- MTMR7 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51665028; called by muse, mutect2, varscan2
- MTMR7 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV51665036; called by muse, mutect2, varscan2
- MTRR | c.84G>A p.M28I (on ENST00000264668; = p.M1? on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV52941985, COSV52942816; called by muse, mutect2, varscan2
- MUC3A | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated, low confidence (0.06); catalogued as COSV60213896; called by muse, mutect2, varscan2
- MUC3A | c.8171C>T p.S2724F | Missense Mutation (SNP) | VAF 161/603 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.635); catalogued as rs774914006, COSV60213903; called by muse, mutect2, varscan2
- MX1 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.217); catalogued as COSV55818793; called by muse, mutect2, varscan2
- MX2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58094801; called by muse, mutect2, varscan2
- MYH10 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52598815; called by muse, mutect2, varscan2
- MYH15 | c.3887G>C p.S1296T | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV56308065; called by muse, varscan2
- MYH15 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as rs748925913, COSV56312226, COSV99842572; called by muse, mutect2, varscan2
- MYH7 | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62516877, COSV62518242; called by muse, varscan2
- MYH9 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99340092; called by muse, varscan2
- MYO10 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1561193741, COSV57019975; called by muse, mutect2, varscan2
- MYO9A | c.750C>G p.N250K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61849667; called by muse, mutect2, varscan2
- MYOM3 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369456651; called by muse, mutect2, varscan2
- MYT1L | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.356); catalogued as COSV67717117; called by muse, mutect2, varscan2
- N4BP2 | c.3523C>T p.P1175S | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54701000, COSV54701067; called by muse, mutect2, varscan2
- N4BP2 | c.4868G>A p.R1623K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54701014; called by muse, mutect2, varscan2
- NAA15 | c.1779G>C p.K593N | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV56718750; called by muse, mutect2, varscan2
- NACA | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1377682007, COSV63269268; called by muse, mutect2, varscan2
- NAF1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.982); catalogued as rs757998387, COSV56804003; called by muse, mutect2, varscan2
- NAGK | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs544314261, COSV54903340; called by muse, mutect2, varscan2
- NAT10 | c.3032G>C p.R1011T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV54394816; called by muse, mutect2
- NAV3 | c.3067G>C p.E1023Q | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs775091711, COSV57073750, COSV57099832; called by muse, mutect2, varscan2
- NAV3 | c.3269C>T p.S1090F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs979890246, COSV57073769; called by muse, mutect2, varscan2
- NBAS | c.5643G>A p.M1881I | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55718265; called by muse, mutect2, varscan2
- NBEAL1 | c.6772G>C p.E2258Q | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV58719735; called by muse, mutect2, varscan2
- NCF4 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV50621320; called by muse, mutect2, varscan2
- NCOA5 | c.1493_1502del p.G498Vfs*22 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as COSV51643836; called by mutect2, pindel, varscan2
- NCOA6 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62862155, COSV62862778; called by muse, mutect2, varscan2
- NCOR2 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs374998878; called by muse, mutect2
- NECTIN2 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52976780; called by muse, mutect2, varscan2
- NEFH | c.2841G>C p.K947N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV100151160, COSV60216415; called by muse, mutect2, varscan2
- NEK2 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV65355755; called by muse, mutect2, varscan2
- NEUROG3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs757577842, COSV54342620, COSV54343128; called by muse, mutect2, varscan2
- NFAT5 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV63026591; called by muse, mutect2, varscan2
- NIPA2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61682529; called by muse, mutect2, varscan2
- NLRC5 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs761339513, COSV52653365, COSV52660649; called by muse, mutect2, varscan2
- NLRP4 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.279); catalogued as COSV56711932; called by muse, mutect2
- NLRX1 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV52703359, COSV52704332; called by muse, varscan2
- NLRX1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV52703372; called by muse, varscan2
- NLRX1 | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs190358411; called by muse, mutect2, varscan2
- NOBOX | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as rs1338860436, COSV56193603; called by muse, mutect2, varscan2
- NOD2 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs143782684; called by muse, mutect2, varscan2
- NOL3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1343625335, COSV50456958; called by muse, mutect2, varscan2
- NOL4 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52344438, COSV52357322; called by muse, mutect2, varscan2
- NOM1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV51979637; called by muse, mutect2, varscan2
- NPAS4 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60649890, COSV60652218; called by muse, mutect2, varscan2
- NPC1L1 | c.2402G>A p.R801K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752677321, COSV56924072, COSV56925549; called by muse, mutect2, varscan2
- NRAP | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.896); catalogued as COSV63489707; called by muse, mutect2, varscan2
- NRARP | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV63082806; called by muse, mutect2
- NRDC | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61401759; called by muse, mutect2, varscan2
- NSD1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.309); catalogued as COSV61774641; called by muse, mutect2, varscan2
- NSD3 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV57668451; called by muse, mutect2, varscan2
- NSUN2 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52953631; called by muse, mutect2, varscan2
- NT5C3B | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54055442; called by muse, mutect2, varscan2
- NTN1 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51480552; called by muse, mutect2, varscan2
- NUP188 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.747); catalogued as rs372967524; called by muse, mutect2, varscan2
- NUP42 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV51728668, COSV51729350; called by muse, mutect2, varscan2
- NUP62 | c.1020G>T p.W340C | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61311826, COSV61313747; called by muse, mutect2, varscan2
- NUP88 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV56704806; called by muse, varscan2
- NUP88 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV56704815; called by muse, varscan2
- NVL | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV55871559; called by muse, mutect2, varscan2
- NXF1 | c.1278C>G p.N426K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53673410; called by muse, mutect2
- NYNRIN | c.2911G>A p.V971I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66841961; called by muse, mutect2, varscan2
- NYNRIN | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV66841964; called by muse, mutect2, varscan2
- OBSCN | c.13738G>A p.E4580K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs981166065, COSV52762918; called by muse, mutect2, varscan2
- OCEL1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | catalogued as rs760775972; called by muse, mutect2, varscan2
- OLFM4 | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV54576749; called by muse, mutect2, varscan2
- OR2AT4 | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV59406809; called by muse, mutect2, varscan2
- OR2T3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV62082197; called by muse, mutect2, varscan2
- OR2V2 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV60315130; called by muse, mutect2, varscan2
- OR51D1 | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 31/189 reads (16%) | catalogued as COSV62913993; called by muse, mutect2, varscan2
- OR51L1 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58624396; called by muse, mutect2, varscan2
- OR52A1 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV61092300; called by muse, mutect2, varscan2
- OR5T2 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs1159406235, COSV57588694; called by muse, mutect2, varscan2
- OR7A17 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV59414144; called by muse, mutect2, varscan2
- OR7D4 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV58071069, COSV58071496, COSV58072540; called by muse, mutect2, varscan2
- OR8J3 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56880167; called by muse, mutect2, varscan2
- OSBPL7 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs764708102, COSV50112160; called by muse, mutect2, varscan2
- OSGEP | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV52831919; called by muse, mutect2, varscan2
- OSGEPL1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51461926, COSV51462182; called by muse, mutect2, varscan2
- OSMR | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV57083893; called by muse, mutect2, varscan2
- OSTF1 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs767694447, COSV60547144; called by muse, mutect2, varscan2
- OTOF | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55500784; called by muse, mutect2, varscan2
- OTUB2 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52573166; called by muse, mutect2, varscan2
- OTUD4 | c.1360G>A p.E454K (on ENST00000447906 / NM_001366057.1; = p.E389K on NM_001102653.1) | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71381752; called by muse, mutect2, varscan2
- OTX1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs776338153, COSV56994461, COSV99246546; called by muse, mutect2, varscan2
- OXR1 | c.1366G>C p.E456Q (on ENST00000442977 / NM_001198532.1; = p.E455Q on NM_018002.3) | Missense Mutation (SNP) | VAF 91/135 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV56327578; called by muse, mutect2, varscan2
- PADI2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.082); catalogued as COSV64945676; called by muse, mutect2, varscan2
- PAGE5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV56943368; called by muse, mutect2, varscan2
- PAN2 | c.2377G>A p.E793K (on ENST00000425394 / NM_001127460.3; = p.E789K on NM_014871.5) | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV57753417; called by muse, mutect2, varscan2
- PAN2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV57753437; called by muse, varscan2
- PAQR7 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV65351600; called by muse, mutect2, varscan2
- PAX1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1188314388, COSV68271558; called by muse, mutect2, varscan2
- PAX3 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1246737713, COSV60587612; called by muse, mutect2, varscan2
- PBRM1 | c.4808_4809del p.R1603Pfs*12 (on ENST00000296302 / NM_001366071.2; = p.R1496Pfs*12 on NM_018313.5) | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as COSV56270656; called by mutect2*, pindel*, varscan2
- PBX2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs773626213, COSV66708712; called by muse, mutect2, varscan2
- PBX4 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52060890, COSV52063107; called by muse, mutect2, varscan2
- PCBP1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs757437176, COSV100340248, COSV57850212; called by muse, mutect2, varscan2
- PCDH17 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1364348588, COSV64971600; called by muse, mutect2, varscan2
- PCDH19 | c.1740C>G p.N580K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs763798306, COSV55260930; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA9 | c.2112C>G p.I704M | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV65325426, COSV65332501; called by muse, mutect2, varscan2
- PCDHB11 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782626028, COSV53375414; called by muse, mutect2, varscan2
- PCDHB4 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs782115208, COSV99522465; called by muse, mutect2, varscan2
- PCDHGA5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53929063; called by muse, mutect2, varscan2
- PCDHGB6 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV53929086; called by muse, mutect2, varscan2
- PCF11 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV53529616; called by muse, varscan2
- PCF11 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV53529856, COSV53531621; called by muse, varscan2
- PCLO | c.7987C>G p.P2663A | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV61627826; called by muse, mutect2, varscan2
- PCNX1 | c.6323C>T p.S2108F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53092811; called by muse, mutect2, varscan2
- PCOLCE | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV53825262; called by muse, mutect2, varscan2
- PDE5A | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs777717408, COSV53347246; called by muse, mutect2, varscan2
- PDE7A | c.1429C>T p.Q477* (on ENST00000401827 / NM_001242318.3; = p.Q451* on NM_002603.4) | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as rs752810107, COSV65153531; called by muse, mutect2, varscan2
- PDGFB | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100483635, COSV58646474; called by muse, mutect2, varscan2
- PGBD4 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as COSV56627469; called by muse, mutect2, varscan2
- PGBD5 | c.661T>C p.C221R (on ENST00000525115; = p.C290R on NM_001258311.2) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58411240; called by muse, mutect2, varscan2
- PHB2 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54641658; called by muse, mutect2, varscan2
- PHKA1 | c.1715-1G>C p.X572_splice | Splice Site (SNP) | VAF 27/40 reads (68%) | catalogued as COSV59804648; called by muse, mutect2, varscan2
- PHRF1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52754418; called by muse, mutect2, varscan2
- PHTF2 | c.773C>G p.S258* (on ENST00000248550 / NM_001366089.1; = p.S220* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99302129; called by muse, mutect2, varscan2
- PI4KB | c.206C>T p.S69F (on ENST00000368873 / NM_001369623.1; = p.S81F on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); catalogued as COSV55016625; called by muse, mutect2
- PIK3C2A | c.4045C>G p.Q1349E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.061); catalogued as COSV56401880; called by muse, mutect2, varscan2
- PIK3R1 | c.2009G>A p.C670Y (on ENST00000521381 / NM_181523.3; = p.C400Y on NM_181504.4) | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128644; called by muse, mutect2, varscan2
- PIKFYVE | c.3071G>A p.G1024E | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV52239680; called by muse, mutect2, varscan2
- PIKFYVE | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs763111855, COSV52239691; called by muse, mutect2, varscan2
- PIP4K2C | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV61605982; called by muse, mutect2, varscan2
- PITPNM3 | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV51470622; called by muse, mutect2, varscan2
- PKM | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756647275, COSV58787800; called by muse, mutect2, varscan2
- PKM | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV58787825; called by muse, mutect2, varscan2
- PLCL1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV70826210; called by muse, mutect2, varscan2
- PLD1 | c.2679C>G p.I893M | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60567065; called by muse, mutect2, varscan2
- PLEC | c.13094C>T p.S4365F (on ENST00000322810 / NM_201380.4; = p.S4255F on NM_000445.5) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV59625025; called by muse, mutect2, varscan2
- PLEC | c.7372G>A p.E2458K (on ENST00000322810 / NM_201380.4; = p.E2348K on NM_000445.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59625085; called by muse, varscan2
- PLEKHA7 | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100850107, COSV63045206; called by muse, mutect2, varscan2
- PLEKHH3 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV53188646; called by muse, mutect2
- PLEKHM1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs768366758, COSV69598693; called by muse, mutect2, varscan2
- PLEKHM2 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV65395875; called by muse, mutect2, varscan2
- PLEKHM3 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66816287; called by muse, mutect2, varscan2
- PLK3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59499592, COSV59501554; called by muse, mutect2, varscan2
- PLPBP | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV60239553; called by muse, mutect2, varscan2
- PLSCR5 | c.344C>G p.T115S | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV71649001; called by muse, mutect2, varscan2
- PLVAP | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs376519104; called by muse, mutect2, varscan2
- PNMA8B | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.526); catalogued as rs377681319; called by muse, mutect2, varscan2
- POLR1A | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV55691748, COSV99807004; called by muse, mutect2
- POLR2E | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV53123867; called by muse, mutect2, varscan2
- POT1 | c.1064A>T p.K355I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV62929396; called by muse, mutect2, varscan2
- POU6F1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61326467; called by muse, mutect2, varscan2
- PPEF2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs903861316, COSV54421711; called by muse, varscan2
- PPEF2 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as rs148045586, COSV54424228; called by muse, varscan2
- PPM1G | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59769160; called by muse, varscan2
- PPP1R10 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV64738930; called by muse, mutect2, varscan2
- PPP1R35 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs574800188; called by muse, mutect2
- PPP6C | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65207591; called by muse, mutect2, varscan2
- PPP6R3 | c.1987G>A p.E663K (on ENST00000393800 / NM_001352375.2; = p.E583K on NM_018312.5) | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.097); catalogued as COSV55724810; called by muse, mutect2, varscan2
- PRC1 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 149/284 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV100727191, COSV62694998; called by muse, mutect2, varscan2
- PRDM14 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1280479464, COSV52571660; called by muse, mutect2, varscan2
- PRDM16 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as CM136479, COSV54586946; called by muse, mutect2, varscan2
- PRDM2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV52445198; called by muse, mutect2, varscan2
- PRDM9 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57005109; called by muse, mutect2, varscan2
- PRICKLE2 | c.667G>A p.E223K (on ENST00000295902; = p.E167K on NM_198859.4) | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55765385; called by muse, mutect2, varscan2
- PRKCD | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as COSV57847848; called by muse, mutect2, varscan2
- PRPF40B | c.1901G>A p.R634Q (on ENST00000380281; = p.R621Q on NM_012272.3) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs773685506, COSV53300552; called by muse, mutect2, varscan2
- PRPH | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as COSV57678296; called by muse, mutect2, varscan2
- PRRC2B | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as COSV61935963; called by muse, mutect2, varscan2
- PRXL2B | c.719C>G p.P240R (on ENST00000444521; = p.P192R on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56520256; called by muse, mutect2, varscan2
- PSD3 | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1292797942, COSV58966821; called by muse, mutect2, varscan2
- PSMB4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415169682, COSV51851176; called by muse, mutect2, varscan2
- PSTPIP2 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); catalogued as rs1338813900, COSV68444061; called by muse, mutect2, varscan2
- PTAR1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as rs1320047477, COSV61208292; called by muse, mutect2, varscan2
- PTCD3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as COSV54479651; called by muse, mutect2, varscan2
- PTDSS1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54632429; called by muse, mutect2, varscan2
- PTGER3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60690104; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.435C>T p.F145= (on ENST00000421990 / NM_001136042.2; = p.F127= on NM_025267.3) | Splice Region (SNP) | VAF 15/50 reads (30%) | catalogued as COSV64182451; called by muse, mutect2, varscan2
- PTK2B | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1435877061, COSV57753541; called by muse, mutect2, varscan2
- PTPN12 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50356281; called by muse, mutect2, varscan2
- PTPRA | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.069); catalogued as COSV53780481; called by muse, mutect2, varscan2
- PTPRF | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV63444257; called by muse, mutect2, varscan2
- PUSL1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs765909677, COSV60088001; called by muse, mutect2, varscan2
- PXYLP1 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs1221210777, COSV53889919; called by muse, mutect2, varscan2
- RAB19 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs570628599, COSV52044393; called by muse, mutect2, varscan2
- RAB23 | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV58097695; called by muse, mutect2, varscan2
- RAB39A | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV100269148, COSV57694721; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV51480967, COSV99920998; called by muse, mutect2, varscan2
- RAB42 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65752997; called by muse, mutect2, varscan2
- RAD54L2 | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV56578000; called by muse, mutect2, varscan2
- RAD9B | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV63777690; called by muse, mutect2, varscan2
- RANBP2 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 107/575 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV51699341; called by muse, mutect2, varscan2
- RANBP2 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 137/781 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51699346; called by muse, mutect2, varscan2
- RASSF7 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV60346705; called by muse, mutect2, varscan2
- RBBP8 | c.2399_2400insC p.K801Efs*14 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as COSV59091808; called by mutect2, pindel*, varscan2
- RBL2 | c.3024C>G p.F1008L | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50875397; called by muse, mutect2, varscan2
- RBM18 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1238898726, COSV52913915; called by muse, mutect2, varscan2
975 further variants in this file (437 protein-altering or splice-affecting, 482 silent, 56 other) are not listed here.
